TCGA case TCGA-CR-7404 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil; Tissue source site: Vanderbilt University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d189a6c6-210f-4957-b500-457d5ce3f867

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Alive.

Diagnoses (5)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C09.9; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 53.5 years (19,532 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,472 days (4.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 18 days; Days to treatment end: 67 days.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 78 days; Days to treatment end: 137 days; Treatment dose: 6,930 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 78 days; Days to treatment end: 137 days; Treatment dose: 5,610 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 78 days; Days to treatment end: 137 days; Treatment dose: 6,930 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 85 days; Days to treatment end: 135 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Days to treatment start: 298 days; Days to treatment end: 354 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 375 days (1.0 years); Days to treatment end: 415 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Days to treatment start: 466 days (1.3 years); Days to treatment end: 599 days (1.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 606 days (1.7 years); Days to treatment end: 634 days (1.7 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Days to treatment start: 1,052 days (2.9 years); Days to treatment end: 1,080 days (3.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 1,297 days (3.6 years); Days to treatment end: 1,318 days (3.6 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Days to treatment start: 1,332 days (3.6 years); Days to treatment end: 1,416 days (3.9 years).
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment end: 627 days (1.7 years); Course number: 2; Treatment anatomic sites: Primary Tumor Field.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Oropharynx, NOS. Age at diagnosis: 54.1 years (19,766 days); Days to diagnosis: 234 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 280 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lymph nodes of head, face and neck. Age at diagnosis: 55.6 years (20,296 days); Days to diagnosis: 764 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 798 days (2.2 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
4. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Cheek mucosa. Age at diagnosis: 56.0 years (20,463 days); Days to diagnosis: 931 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 931 days (2.5 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
5. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mandible. Age at diagnosis: 56.2 years (20,531 days); Days to diagnosis: 999 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,171 days (3.2 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 234 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Oropharynx, NOS; Days to recurrence: 234 days.
- Day 764 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to recurrence: 764 days (2.1 years).
- Day 931 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Cheek mucosa; Days to recurrence: 931 days (2.5 years).
- Day 999 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mandible; Days to recurrence: 999 days (2.7 years).
- Days to follow up: 1,472 days (4.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A: Positive.
- Involved Tissue, NOS human papillomavirus (ISH): Positive.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CR-7404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.2; Intermediate dimension: 0.2; Shortest dimension: 0.1.
  Slide TCGA-CR-7404-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-CR-7404-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 1; Alcohol history documented: Yes.
- Drug treatment 6: Pharmaceutical therapy drug name: Xeloda.
- Drug treatment 10: Clinical trial drug classification: Phase I Trial; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES.
- Follow-up form 1: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event site: Oral Cavity; New tumor event site other: Buccal muco; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event site: Cervical Lymph Nodes; New tumor event site other: Right submandibular neck; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event site: Oropharynx; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Persistent Disease.
- Follow-up form 4: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event site: Oral Cavity; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,472 days; disease-specific survival: no event (censored), 1,472 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 234 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CR-7404-01A-11D-2128-01): tumor purity 0.4, ploidy 1.98, whole-genome doublings 0.
